Somatic mutation profile of tumor specimen TCGA-OR-A5KZ-01A (aliquot TCGA-OR-A5KZ-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KZ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 42.7 years (15,594 days).
Specimen TCGA-OR-A5KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91ce9b73-47ca-43fb-905a-cc9fc2525fd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KZ-10A (Blood Derived Normal), aliquot TCGA-OR-A5KZ-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70eb406c-1b40-48ea-bcd1-bbd0bcc5954d

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.538_552del p.E180_D184del | In Frame Del (DEL) | VAF 110/135 reads (81%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- C18orf25 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 146/159 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV56367567; called by muse, mutect2, varscan2
- CNTN3 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 66/75 reads (88%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs187262258, COSV55175910; called by muse, mutect2, varscan2
- DAAM1 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760791831, COSV62835152; called by muse, mutect2, varscan2
- HSPA13 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1185004634; called by muse, mutect2, varscan2
- NF1 | c.2324_2325+8del p.X775_splice | Splice Site (DEL) | VAF 59/78 reads (76%) | catalogued as COSV100645973; called by mutect2, pindel, varscan2
- ST18 | c.2577G>C p.W859C | Missense Mutation (SNP) | VAF 157/306 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99390734; called by muse, mutect2, varscan2
- VGLL3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1335449303, COSV67352631; called by muse, varscan2
- ALAD | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEBPB | c.333del p.Q113Sfs*28 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- EGFR | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- EPB41L5 | c.559_560del p.F187Qfs*8 | Frame Shift Del (DEL) | VAF 47/65 reads (72%) | called by mutect2, pindel, varscan2
- GALNT5 | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GNPDA1 | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IFT140 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 47/149 reads (32%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.1034A>G p.Y345C (on ENST00000418998 / NM_001377303.1; = p.Y255C on NM_015478.7) | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGEF1A | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- SERPINA10 | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- SNCAIP | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SPECC1L | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STAU2 | c.1501G>C p.E501Q (on ENST00000524300 / NM_001164380.2; = p.E469Q on NM_014393.2) | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- SVEP1 | c.6350T>A p.V2117E | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZZZ3 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DENND6A | c.1482C>G p.T494= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- PLXNA2 | c.5397C>G p.L1799= | Silent (SNP) | VAF 137/153 reads (90%) | catalogued as rs894748074; called by muse, mutect2, varscan2
- TRIO | c.3777C>T p.L1259= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV60080068; called by muse, mutect2, varscan2
- MIR520F | n.68T>C | RNA (SNP) | VAF 126/204 reads (62%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7303del | Intron (DEL) | VAF 9/18 reads (50%) | called by mutect2, varscan2
